Somatic mutation profile of tumor specimen TCGA-HT-7686-01A (aliquot TCGA-HT-7686-01A-11D-2253-08) from TCGA case TCGA-HT-7686, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 29.4 years (10,724 days).
Specimen TCGA-HT-7686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59bbeba1-2d66-4742-955d-b497acfb29e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7686-10A (Blood Derived Normal), aliquot TCGA-HT-7686-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ac16218-d69d-4f8a-939f-85386619de96

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 14/18 reads (78%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AK7 | c.1721T>C p.F574S | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745430577, COSV50869458; called by muse, mutect2, varscan2
- CCNB3 | c.3372T>A p.S1124R | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.474); catalogued as COSV52070618; called by muse, mutect2, varscan2
- EPPK1 | c.6035C>A p.A2012D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73260792, COSV73260902; called by muse, mutect2, varscan2
- MYH2 | c.4163G>A p.R1388H | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs745754711, COSV55432911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1L1 | c.881T>C p.F294S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV65738701; called by muse, mutect2, varscan2
- PLCH1 | c.3127A>G p.I1043V (on ENST00000340059 / NM_001130960.2; = p.I1035V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV58189267; called by muse, mutect2, varscan2
- PRDM16 | c.3074G>A p.R1025Q | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs1269754129, COSV54581093; called by muse, mutect2
- PRDM9 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs746973453, COSV57003391, COSV57006333; called by muse, mutect2, varscan2
- TUBG1 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV52220658; called by muse, mutect2, varscan2
- UBAP1 | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52657646; called by muse, mutect2, varscan2
- UNC5CL | c.1358C>A p.P453H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55109184; called by muse, mutect2, varscan2
- ATRX | c.3853del p.S1285Pfs*61 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- ADAM28 | c.1950A>G p.G650= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV56098375; called by muse, mutect2, varscan2
- ANXA10 | c.879T>C p.Y293= | Silent (SNP) | VAF 59/149 reads (40%) | catalogued as rs757899155, COSV63738253; called by muse, mutect2, varscan2
- DHX29 | c.2028C>G p.L676= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV52416934; called by muse, mutect2, varscan2
- HCN1 | c.2340C>A p.T780= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs746392507, COSV100299237, COSV57491654; called by muse, mutect2, varscan2
- AC073310.1 | n.376G>A | RNA (SNP) | VAF 36/204 reads (18%) | catalogued as rs145740138; called by muse, mutect2, varscan2
